Somatic mutation profile of tumor specimen TARGET-20-PANBZH-09A (aliquot TARGET-20-PANBZH-09A-02D) from TARGET case TARGET-20-PANBZH, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.7 years (3,921 days).
Specimen TARGET-20-PANBZH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 608afd73-e045-4776-b227-24e6f169e4af.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANBZH-14A (Bone Marrow Normal), aliquot TARGET-20-PANBZH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f8a0499-99ea-476d-ae93-5dc8840a995f

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.15061C>T p.R5021* | Nonsense Mutation (SNP) | VAF 11/157 reads (7%) | catalogued as rs587783695, CM122109, COSV56415919; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- KMT2D | c.14878C>T p.R4960* | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as rs1555185969, CM111922, COSV56424402; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.16229G>A p.G5410E | Missense Mutation (SNP) | VAF 135/287 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56424384; called by muse, mutect2, varscan2
- WT1 | c.1069C>G p.R357G | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.597); catalogued as CM971594, COSV60067818, COSV60068249, COSV60071382, COSV60073329, COSV60074859, COSV60075137; called by muse, varscan2
